Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JM-01A (Primary Tumor).

[page 1 of 4]
Deceased M

(170.0cm 75.7kg BSA: 1.89m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) TOTAL LARYNGEAL PHARYNGECTOMY

INVASIVE SQUAMOUS CARCINOMA MODERATELY DIFFERENTIATED, IN LEFT PIRIFORM SINUS AND PHARYNX

Tumor Features:

Gross: Ulcerating

Size: 7.0 cm in largest dimension

Invasion: Present, depth 2.0 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Absent (entrapped nerves)

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending Decalcification (see addendum)

Lymphocyte Infiltration: Mild

Mucosal Margin: (en-face) Negative for invasive carcinoma

Deep Margin: (radial) Negative for invasive carcinoma

Dysplasia at Margin: Present, Severe dysplasia at left pharynx margin(s).

Thyroid, no tumor present

Four perilaryngeal lymph nodes, negative for tumor

(B) LEFT LATERAL PHARYNGEAL WALL:

Squamous mucosa, no tumor present.

(C) LEFT NECK DISSECTION, LEVEL II:

Five lymph nodes, no tumor present (0/5).

(D) LEFT NECK DISSECTION, LEVEL III:

Five lymph nodes, no tumor present (0/5).

(E) LEFT NECK DISSECTION, LEVEL IV:

Five lymph nodes, no tumor present (0/5).

(F) RIGHT NECK DISSECTION, LEVEL II "B":

Five lymph nodes, no tumor present (0/5).

(G) LEFT SUPERIOR MARGIN:

Squamous mucosa and minor salivary glands, no tumor present.

(H) RIGHT NECK DISSECTION, LEVEL III:

Nine lymph nodes, no tumor present (0/9).

(I) RIGHT NECK DISSECTION, LEVEL IV:

Four lymph nodes, no tumor present (0/4).

(J) RIGHT NECK DISSECTION, LEVEL II "A":

Five lymph nodes, no tumor present (0/5).

ICD-O-3 NOS
Carcinoma, squamous cell
8670/3
Site CGLF
Larynx NOS C32.9
path
Posterior wall of pharynx NOS
C14.8
8/9/13

GROSS DESCRIPTION

(A) TOTAL LARYNGEAL PHARYNGECTOMY (CHECK ALL MARGINS) – A total laryngopharyngectomy specimen (9 x 7.5 x 5.5 cm total), including attached unremarkable hyoid cartilage, thyroid cartilage, larynx with unremarkable mucosal surface including the supraglottis, glottis, and subglottis and inferiorly connected with segment of trachea and proximal esophagus (4 cm in length). Unremarkable thyroid gland including the right (5 x 2 x 1.6), left lobe (4 x 3 x 1.3 cm) and isthmus, anterior soft tissue including skeletal muscle (6.5 x 6.5 x 1.5 cm).

Located in the posterior pharyngeal wall, involving the left piriform sinus soft tissue, is a large irregular firm tumor mass (7

[page 2 of 4]
Accession: Deceased M (170.0cm 75.7kg BSA: 1.82m²)
Specimen Date/Time:

x 6.6 x 2 cm) with mucosal surface ulceration and necrosis. Tumor measures 1.4 cm from the closest posterior esophageal wall resection margin, 0.3 cm from the closest right superior pharyngeal mucosa edge, abutting but not involving the posterior soft tissue margin. Tumor extends into the posterior portion of the left piriform sinus soft tissue, 2 cm from the closest piriform mucosal edge. Tumor is not grossly involving the thyroid cartilage. Bone has submitted to bone lab for further decalcification assessment.

The epiglottis has very focal mucosal erosion. No tumor extends into the glottis, including the vocal cord. All the right and left lateral mucosal, esophageal mucosa and base of the tongue mucosa are taken for frozen section evaluation. Representative sections of tumor submitted subsequently.

The thyroid cartilage is sectioned to reveal a grossly unremarkable cut surface. Representative sections of the left thyroid cartilage are submitted in A23 and A24 after decalcification.

SECTION CODE: A1, right posterior, and right lateral mucosal margin, en face; A2, left lateral mucosal margin, en face; A3, posterior esophageal wall, en face; A4, anterior esophageal wall and posterior trachea wall, en face; A5, mucosal margin at right base tongue, en face; A6, mucosal margin at left base of the tongue, en face; A7-A8, tumor in relation to right epiglottic fold, posterior hypopharyngeal wall; A9-A10, tumor with involved posterior hypopharyngeal wall with the deepest invasion; A11-A12, tumor with involved left epiglottic mucosal fold; A13, tumor with involved left piriform sinus mucosa; A14, left piriform sinus mucosa, non tumor involved; A15, tumor to the closest posterior invasion on the left; A16, extension the mostly inferior tracheal edge; A17, left vocal cord; A18, right vocal cord; A19, right thyroid; A20, left thyroid; A21-22, five possible lymph nodes.

*FS/DX: AT LEAST CARCINOMA IN SITU OF LEFT PHARYNX/LEFT BASE OF TONGUE REGIONS, REMAINDER OF MUCOSAL MARGINS NEGATIVE.

(B) LEFT LATERAL PHARYNGEAL WALL –

*FS/DX: NEGATIVE FOR TUMOR.

(C) LEFT NECK DISSECTION LEVEL 2 – An unoriented portion of soft tissue measuring 4 x 3 x 1.5 cm which contains multiple lymph node candidates. All candidates are entirely submitted.

SECTION CODE: C1, two lymph node candidates; C2, three candidate lymph nodes; C3, one lymph node candidate.

(D) LEFT NECK DISSECTION LEVEL 3 – An unoriented portion of fibroadipose tissue measuring 7 x 2 x 1 cm. The specimen contains multiple lymph node candidates which are entirely submitted.

SECTION CODE: D1, three lymph node candidates; D2, two candidate lymph nodes; D3, one candidate node bisected.

(E) LEFT NECK DISSECTION LEVEL 4 – An unoriented portion of fibroadipose tissue measuring 4 x 4 x 1 cm. Multiple candidate lymph nodes are identified which are entirely submitted.

SECTION CODE: E1, four lymph node candidates; E2, two lymph node candidates; E3-E4, one candidate node bisected.

(F) RIGHT NECK DISSECTION LEVEL 2B – A portion of fibroadipose tissue measuring 2 x 1.5 x 1 cm. The specimen contains two lymph node candidates. The specimen is entirely submitted.

SECTION CODE: F1, one lymph node candidate; F2-F3, one lymph node candidate bisected.

(G) LEFT SUPERIOR MARGIN – Unoriented portion of tan-pink soft tissue (1.0 x 0.5 x 0.4 cm) that is submitted entirely in G for frozen section evaluation.

*FS/DX: NEGATIVE FOR CARCINOMA.

(H) RIGHT NECK LEVEL 3 – An unoriented portion of fibroadipose tissue measuring 4.5 x 2.5 x 1 cm. The specimen contains multiple lymph node candidates which are entirely submitted.

SECTION CODE: H1-H2, four lymph node candidates in each; H5, five candidate lymph nodes.

(I) RIGHT NECK DISSECTION LEVEL 4 – An unoriented portion of fibroadipose tissue measuring 3 x 2.5 x 1 cm. The examination reveals multiple candidate lymph nodes which are entirely submitted.

SECTION CODE: I1, three lymph node candidates; I2, two lymph node candidates.

(J) RIGHT NECK DISSECTION LEVEL 2A – An unoriented portion of fibroadipose tissue measuring 4 x 2.5 x 1 cm. The specimen contains multiple lymph node candidates which are entirely submitted.

SECTION CODE: J1, two candidate lymph nodes; J2, three lymph node candidates.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 3 of 4]
Page: 3

Deceased M

1170.Ccm 75.7kg BSA: 1.89m²

Accession:

Specimen Date/Time:

T-55000, M-80703, M-43000, M-Y4030,

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 4 of 4]
Deceased M

(170.0cm 75.7kg BSA: 1.69m²)

Accession:

Specimen Date/Time:

ADDENDUM

This modified report is being issued to report the results of decalcification.

COMMENT

Additional sections reviewed on part A) TOTAL LARYNGEAL PHARYNGECTOMY are negative for cartilage invasion.

GROSS DESCRIPTION

(A) TOTAL LARYNGEAL PHARYNGECTOMY: Grossly the tumor approximates the thyroid cartilage without invasion.

ADDITIONAL SECTION CODE: (A1-A6 frozen section evaluation); A23, A24 section of left thyroid cartilage closest to tumor for decalcification.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Discrepancy		✓
HPV SA Discrepancy		✓
Print Immunohistochemistry		✓

Source: NCI Genomic Data Commons file bc7e4015-78e2-4df1-9ab1-353eed0609b3 (TCGA-CV-A6JM.03654678-03F9-41FE-9DD1-0C5A391F7AA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).